Somatic mutation profile of tumor specimen 0DR9C6 from CCDI case PBCGDF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,980 days).
Specimen 0DR9C6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5312b50d-8b16-40c9-a3fc-af4cbb837112.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR9CT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6471b27c-2ced-45d4-a1ae-92746e39779c

The open-access MAF lists 53 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Intron 5, Nonsense Mutation 4, 5'UTR 3, Frame Shift Del 2, 3'UTR 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 527/1142 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV64731793, COSV64731830, COSV64732212; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 477/771 reads (62%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 250/807 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 441/721 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs772323233, COSV59205287; called by muse, varscan2
- CENPF | c.1456_1458del p.K486del | In Frame Del (DEL) | VAF 359/828 reads (43%) | catalogued as rs1416743580; called by pindel, varscan2
- CNTN6 | c.2715A>T p.Q905H | Missense Mutation (SNP) | VAF 743/1711 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs777124095, COSV100610590; called by muse, mutect2, varscan2
- FNDC3B | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 683/1372 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61037658; called by muse, mutect2, varscan2
- GRB7 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 267/674 reads (40%) | catalogued as rs1203400544, COSV100485351; called by muse, mutect2, varscan2
- ITPK1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 350/547 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50896533, COSV99968439; called by muse, mutect2, varscan2
- LOXL1 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 419/961 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772638560, COSV56093378; called by muse, mutect2, varscan2
- MCM2 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 586/1305 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs772439652; called by muse, varscan2
- PDGFRA | c.950T>A p.I317N | Missense Mutation (SNP) | VAF 2355/2889 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV57269002; called by muse, mutect2, varscan2
- RIPK4 | c.2482C>T p.R828W (on ENST00000352483; = p.R780W on NM_020639.3) | Missense Mutation (SNP) | VAF 237/832 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs140909597; called by muse, mutect2, varscan2
- SH3RF3 | c.2105C>A p.P702H | Missense Mutation (SNP) | VAF 553/1193 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as rs1209593358; called by muse, mutect2, varscan2
- SPTA1 | c.6631C>T p.R2211C | Missense Mutation (SNP) | VAF 919/2039 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs773800556, COSV63752742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEP1 | c.4820G>A p.R1607H | Missense Mutation (SNP) | VAF 764/1982 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs986359838, COSV99402090; called by muse, mutect2, varscan2
- TMEM140 | c.333_334del p.R111Sfs*65 | Frame Shift Del (DEL) | VAF 382/1687 reads (23%) | catalogued as rs762677084; called by pindel, varscan2
- TTLL7 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 1169/2504 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV53088745; called by muse, mutect2, varscan2
- WFDC1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 572/1170 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs145066295; called by muse, varscan2
- YAF2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 454/2130 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs769223015, COSV100586509, COSV100586515; called by muse, mutect2, varscan2
- ZNF512B | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 568/1246 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs754512161, COSV53871004; called by muse, mutect2
- ATRX | c.5371_5372del p.D1791Ffs*18 | Frame Shift Del (DEL) | VAF 724/995 reads (73%) | called by mutect2, pindel, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 140/2269 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ENAM | c.2105A>C p.Y702S | Missense Mutation (SNP) | VAF 287/1212 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- GAREM1 | c.2555C>G p.S852* (on ENST00000269209 / NM_001242409.2; = p.S851* on NM_022751.3) | Nonsense Mutation (SNP) | VAF 28/758 reads (4%) | called by muse, mutect2
- HHLA2 | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 391/1586 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ITPRID1 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 889/3042 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- KCNC1 | c.1150T>A p.F384I | Missense Mutation (SNP) | VAF 336/762 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LMX1B | c.1094T>G p.L365* (on ENST00000373474 / NM_001174147.2; = p.L358* on NM_002316.4) | Nonsense Mutation (SNP) | VAF 234/1308 reads (18%) | called by muse, varscan2
- PRDM15 | c.2206C>G p.H736D | Missense Mutation (SNP) | VAF 425/1470 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- RPA4 | c.578A>T p.N193I | Missense Mutation (SNP) | VAF 642/659 reads (97%) | SIFT tolerated (0.38); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 111/2071 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2
- ZDBF2 | c.5588G>C p.C1863S | Missense Mutation (SNP) | VAF 944/1898 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 134/2485 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- C1orf127 | c.2052A>T p.G684= | Silent (SNP) | VAF 50/1204 reads (4%) | called by muse, mutect2
- CAPN5 | c.294C>T p.C98= (on ENST00000456580; = p.C58= on NM_004055.5) | Silent (SNP) | VAF 60/1898 reads (3%) | catalogued as rs782261995; called by muse, mutect2
- CHST12 | c.279G>A p.A93= | Silent (SNP) | VAF 265/1593 reads (17%) | catalogued as rs202038444; called by muse, mutect2, varscan2
- CMTR1 | c.1542C>T p.I514= | Silent (SNP) | VAF 817/1437 reads (57%) | called by muse, mutect2, varscan2
- MINDY1 | c.330G>A p.E110= | Silent (SNP) | VAF 507/1041 reads (49%) | called by muse, mutect2, varscan2
- NXPH4 | c.798C>G p.A266= | Silent (SNP) | VAF 54/1284 reads (4%) | called by muse, mutect2
- REN | c.321G>A p.S107= | Silent (SNP) | VAF 764/1659 reads (46%) | catalogued as rs371626384; called by muse, mutect2, varscan2
- TBC1D12 | c.1395G>T p.L465= | Silent (SNP) | VAF 50/1238 reads (4%) | called by muse, mutect2
- COMP | c.1136-76C>G | Intron (SNP) | VAF 20/364 reads (5%) | catalogued as rs866516146; called by muse, mutect2
- DIS3 | c.*83G>C | 3'UTR (SNP) | VAF 72/303 reads (24%) | called by muse, mutect2, varscan2
- GATB | c.641-25G>A | Intron (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- GLS | c.979+65G>A | Intron (SNP) | VAF 217/421 reads (52%) | catalogued as rs1158681601; called by muse, mutect2, varscan2
- KIF21A | c.3960-55A>G | Intron (SNP) | VAF 224/814 reads (28%) | catalogued as rs767380907; called by muse, varscan2
- MPP6 | c.652-81C>G | Intron (SNP) | VAF 263/398 reads (66%) | called by muse, mutect2, varscan2
- OST4 | c.-12_-11del | 5'UTR (DEL) | VAF 133/370 reads (36%) | catalogued as rs1272091071; called by pindel, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 70/650 reads (11%) | called by muse, varscan2
- SERPINB8 | c.*23C>T | 3'UTR (SNP) | VAF 461/477 reads (97%) | catalogued as rs976554110; called by muse, mutect2, varscan2
- SPATA31C2 | n.65C>A | RNA (SNP) | VAF 513/2560 reads (20%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.-37G>C | 5'UTR (SNP) | VAF 400/945 reads (42%) | called by muse, mutect2, varscan2
